Somatic mutation profile of tumor specimen ALCH-AFDI-TTP1-A (aliquot ALCH-AFDI-TTP1-A-1-0-D-A673-36) from ALCHEMIST case ALCH-AFDI, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.1 years (21,939 days).
Specimen ALCH-AFDI-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 21e78122-d05e-4652-ae8b-2ed9fcfcefb7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AFDI-NB1-A (Blood Derived Normal), aliquot ALCH-AFDI-NB1-A-1-0-D-A673-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/35507896-d322-49f6-9982-72c702f94d6f

The open-access MAF lists 269 somatic variants for this specimen: 191 protein-altering or splice-affecting, 41 silent, 37 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 168, Silent 41, Intron 17, Nonsense Mutation 11, 3'UTR 7, 5'UTR 6, Frame Shift Del 4, 5'Flank 3, Frame Shift Ins 3, RNA 3, In Frame Del 2, Splice Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 90/309 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACOT12 | c.1495G>T p.A499S | Missense Mutation (SNP) | VAF 45/166 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV56895160; called by muse, mutect2, varscan2
- ADGB | c.4031C>A p.P1344H | Missense Mutation (SNP) | VAF 53/194 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.535); catalogued as COSV58847869; called by muse, mutect2, varscan2
- AGA | c.21G>C p.L7F | Missense Mutation (SNP) | VAF 156/521 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.201); catalogued as rs537097287; called by muse, mutect2, varscan2
- AHNAK | c.7532C>T p.P2511L | Missense Mutation (SNP) | VAF 97/424 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.208); catalogued as rs998622482; called by muse, mutect2, varscan2
- BMPER | c.1312G>A p.V438M | Missense Mutation (SNP) | VAF 60/250 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs373894849, COSV51819315; called by muse, mutect2, varscan2
- C8A | c.350del p.G117Efs*43 | Frame Shift Del (DEL) | VAF 198/583 reads (34%) | catalogued as COSV63484714; called by mutect2, pindel, varscan2
- CATSPERB | c.2897T>C p.L966S | Missense Mutation (SNP) | VAF 81/435 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.124); catalogued as rs757897627; called by muse, mutect2, varscan2
- CCDC141 | c.1879T>C p.F627L | Missense Mutation (SNP) | VAF 116/558 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.251); catalogued as rs746816090; called by muse, mutect2, varscan2
- CCDC168 | c.15141dup p.L5048Ifs*6 | Frame Shift Ins (INS) | VAF 84/285 reads (29%) | catalogued as rs1248067507; called by mutect2, pindel, varscan2
- CCDC186 | c.745A>G p.N249D | Missense Mutation (SNP) | VAF 126/565 reads (22%) | SIFT tolerated (0.62); PolyPhen benign (0.015); catalogued as rs200818122; called by muse, mutect2, varscan2
- CFHR1 | c.749C>T p.T250I | Missense Mutation (SNP) | VAF 104/413 reads (25%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.999); catalogued as rs773213564; called by muse, mutect2, varscan2
- CNGB1 | c.2873G>A p.S958N | Missense Mutation (SNP) | VAF 61/455 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.235); catalogued as rs1414083701; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNGB1 | c.769G>T p.A257S | Missense Mutation (SNP) | VAF 78/246 reads (32%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.097); catalogued as rs771075912; called by muse, mutect2, varscan2
- CNTN6 | c.3041T>C p.I1014T | Missense Mutation (SNP) | VAF 67/608 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs759673553, COSV100611925; called by muse, mutect2, varscan2
- COL17A1 | c.4460G>A p.R1487Q | Missense Mutation (SNP) | VAF 86/736 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as rs148509618, COSV100211833; called by muse, mutect2, varscan2
- CPS1 | c.1483G>A p.V495I | Missense Mutation (SNP) | VAF 125/433 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.258); catalogued as COSV51808031; called by muse, mutect2, varscan2
- CSTF2T | c.1123C>T p.P375S | Missense Mutation (SNP) | VAF 90/302 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1435126491; called by muse, mutect2, varscan2
- CTDP1 | c.2666G>A p.R889Q | Missense Mutation (SNP) | VAF 78/328 reads (24%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.023); catalogued as rs112476862; called by muse, mutect2, varscan2
- CUL4A | c.510C>G p.I170M (on ENST00000375440 / NM_001008895.4; = p.I70M on NM_003589.3) | Missense Mutation (SNP) | VAF 61/153 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.398); catalogued as COSV58376778; called by muse, mutect2, varscan2
- CYLC1 | c.747G>T p.M249I | Missense Mutation (SNP) | VAF 41/247 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.013); catalogued as rs945902243; called by muse, mutect2, varscan2
- DALRD3 | c.526C>T p.R176W (on ENST00000341949 / NM_001009996.3; = p.R9W on NM_018114.5) | Missense Mutation (SNP) | VAF 77/238 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as rs1559906286; called by muse, mutect2, varscan2
- DNAH5 | c.6637C>G p.L2213V | Missense Mutation (SNP) | VAF 193/836 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV54253101, COSV54259614, COSV99448395; called by muse, mutect2, varscan2
- DNMT3A | c.428G>A p.R143Q | Missense Mutation (SNP) | VAF 68/283 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs745432645, COSV53062004; called by muse, mutect2, varscan2
- DPEP3 | c.301C>T p.P101S | Missense Mutation (SNP) | VAF 59/225 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1407533524, COSV52050657; called by muse, mutect2, varscan2
- DUSP9 | c.907G>C p.A303P | Missense Mutation (SNP) | VAF 67/277 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61438574; called by muse, mutect2, varscan2
- FBN1 | c.5959G>T p.G1987C | Missense Mutation (SNP) | VAF 223/1087 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM012600, COSV57317350; called by muse, mutect2, varscan2
- FEZF1 | c.812C>T p.A271V | Missense Mutation (SNP) | VAF 86/432 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as COSV58659765; called by muse, mutect2, varscan2
- GABRG1 | c.356G>T p.W119L | Missense Mutation (SNP) | VAF 119/351 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54954790; called by muse, mutect2, varscan2
- GRM8 | c.2722A>G p.I908V | Missense Mutation (SNP) | VAF 279/648 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs143754269; called by muse, mutect2, varscan2
- HNRNPR | c.1352G>A p.R451H | Missense Mutation (SNP) | VAF 61/357 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.375); catalogued as rs773384635, COSV56422528; called by muse, mutect2, varscan2
- IFI44L | c.695G>T p.G232V | Missense Mutation (SNP) | VAF 143/366 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs75931592; called by muse, mutect2, varscan2
- ITGA2B | c.1109C>T p.A370V | Missense Mutation (SNP) | VAF 81/228 reads (36%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs571678984, COSV99289396; called by muse, mutect2, varscan2
- ITPR2 | c.2455A>G p.I819V | Missense Mutation (SNP) | VAF 36/276 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as rs978532953; called by muse, mutect2, varscan2
- KATNAL2 | c.673G>A p.A225T (on ENST00000356157 / NM_001353899.1; = p.A153T on NM_031303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 78/256 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0.028); catalogued as rs1345210198; called by muse, mutect2, varscan2
- KCNH2 | c.818G>T p.R273L | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.298); catalogued as CM070177; called by muse, mutect2, varscan2
- KCNQ2 | c.2353G>A p.D785N (on ENST00000359125 / NM_172107.4; = p.D757N on NM_004518.6) | Missense Mutation (SNP) | VAF 53/197 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1176290657, COSV60540031; called by muse, mutect2, varscan2
- KIF15 | c.3916G>C p.E1306Q | Missense Mutation (SNP) | VAF 89/340 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.076); catalogued as COSV58158930, COSV58161787; called by muse, mutect2, varscan2
- KLHL1 | c.1393G>A p.G465R | Missense Mutation (SNP) | VAF 57/220 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64780805; called by muse, mutect2, varscan2
- KLHL40 | c.1567C>A p.L523M | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as COSV99825446; called by muse, mutect2, varscan2
- LTBP3 | c.2251G>A p.G751S | Missense Mutation (SNP) | VAF 85/294 reads (29%) | SIFT tolerated (0.45); PolyPhen probably damaging (1); catalogued as rs1181866135; called by muse, mutect2, varscan2
- MAGEL2 | c.2585C>T p.P862L | Missense Mutation (SNP) | VAF 78/283 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.876); catalogued as COSV99041386; called by muse, mutect2, varscan2
- MAP3K12 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); catalogued as COSV99912999; called by muse, varscan2
- MAPK13 | c.566G>T p.R189L | Missense Mutation (SNP) | VAF 31/257 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52982325; called by muse, mutect2, varscan2
- MCOLN2 | c.646T>C p.Y216H | Missense Mutation (SNP) | VAF 160/431 reads (37%) | SIFT tolerated (0.78); PolyPhen benign (0.04); catalogued as rs763234594; called by muse, mutect2, varscan2
- MSRB3 | c.518G>T p.G173V | Missense Mutation (SNP) | VAF 103/561 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as COSV57590135; called by muse, mutect2, varscan2
- NELL1 | c.1448G>T p.G483V | Missense Mutation (SNP) | VAF 73/256 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54242531; called by muse, mutect2, varscan2
- OR52B4 | c.597G>A p.W199* | Nonsense Mutation (SNP) | VAF 22/386 reads (6%) | catalogued as rs567391276; called by muse, mutect2
- P3H2 | c.1391G>T p.R464L | Missense Mutation (SNP) | VAF 63/662 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60024619; called by muse, mutect2
- PITPNM2 | c.373G>A p.V125M | Missense Mutation (SNP) | VAF 56/240 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760673439; called by muse, mutect2, varscan2
- PRPS1L1 | c.694G>C p.A232P | Missense Mutation (SNP) | VAF 16/372 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV72649781; called by muse, mutect2
- PRTN3 | c.143G>C p.R48P | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.109); catalogued as rs1460718981; called by muse, mutect2
- RCL1 | c.754G>A p.G252S | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); catalogued as rs765978714; called by muse, mutect2, varscan2
- SDC1 | c.557C>T p.S186F | Missense Mutation (SNP) | VAF 35/141 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.827); catalogued as rs1368561417; called by muse, mutect2, varscan2
- SEC24C | c.142G>C p.V48L | Missense Mutation (SNP) | VAF 56/177 reads (32%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as rs1206999969, COSV59541388; called by muse, mutect2, varscan2
- SEMA6A | c.463T>C p.F155L | Missense Mutation (SNP) | VAF 123/427 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57314886; called by muse, mutect2, varscan2
- SLC25A47 | c.422C>T p.P141L | Missense Mutation (SNP) | VAF 137/649 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.097); catalogued as rs759660610, COSV62309674; called by muse, mutect2, varscan2
- SLC37A2 | c.332G>A p.R111Q | Missense Mutation (SNP) | VAF 37/278 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs745958927; called by muse, mutect2, varscan2
- SPIN4 | c.141C>G p.H47Q | Missense Mutation (SNP) | VAF 38/271 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV58738374; called by muse, mutect2, varscan2
- TENM3 | c.7761C>A p.N2587K | Missense Mutation (SNP) | VAF 51/198 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.186); catalogued as COSV101305286, COSV69306153; called by muse, mutect2, varscan2
- TMEM164 | c.145G>T p.A49S | Missense Mutation (SNP) | VAF 91/300 reads (30%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV55815100; called by muse, mutect2, varscan2
- TRPM1 | c.802C>A p.L268M | Missense Mutation (SNP) | VAF 131/547 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56631649; called by muse, mutect2, varscan2
- TSSK1B | c.314G>C p.R105P | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.745); catalogued as COSV66814886; called by muse, mutect2, varscan2
- TTN | c.87274G>C p.G29092R (on ENST00000591111; = p.G21668R on NM_003319.4) | Missense Mutation (SNP) | VAF 29/161 reads (18%) | PolyPhen probably damaging (0.992); catalogued as COSV59884474; called by muse, mutect2, varscan2
- TTN | c.20596T>A p.C6866S (on ENST00000591111; = p.C5939S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 117/537 reads (22%) | PolyPhen benign (0.223); catalogued as COSV59907309; called by muse, mutect2, varscan2
- UNC13C | c.4712C>A p.P1571Q | Missense Mutation (SNP) | VAF 78/270 reads (29%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.068); catalogued as COSV52843067, COSV52932233; called by muse, mutect2, varscan2
- UPF2 | c.1477A>G p.K493E | Missense Mutation (SNP) | VAF 139/398 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs778344959; called by muse, mutect2, varscan2
- ZBBX | c.905G>A p.W302* | Nonsense Mutation (SNP) | VAF 50/184 reads (27%) | catalogued as COSV100285117, COSV56795726; called by muse, varscan2
- ZNF716 | c.783A>C p.R261S | Missense Mutation (SNP) | VAF 87/368 reads (24%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.876); catalogued as COSV101348676; called by muse, mutect2, varscan2
- ZSWIM8 | c.2680C>G p.L894V | Missense Mutation (SNP) | VAF 10/240 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs1195069272; called by muse, mutect2
- ADGRF3 | c.2427_2430del p.H809Qfs*103 (on ENST00000311519 / NM_001145168.1; = p.H610Qfs*103 on NM_153835.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 100/526 reads (19%) | called by mutect2, pindel, varscan2
- ADGRG4 | c.5579T>G p.M1860R | Missense Mutation (SNP) | VAF 143/427 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- ALDH16A1 | c.305C>T p.A102V | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- AQR | c.4080G>T p.Q1360H | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGEF33 | c.1481C>A p.S494* | Nonsense Mutation (SNP) | VAF 89/397 reads (22%) | called by muse, mutect2, varscan2
- ARMC5 | c.463A>T p.I155L | Missense Mutation (SNP) | VAF 48/333 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- ATG10 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 189/656 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ATXN1L | c.699G>T p.M233I | Missense Mutation (SNP) | VAF 72/293 reads (25%) | SIFT tolerated (0.52); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- BRWD3 | c.2471C>A p.S824* | Nonsense Mutation (SNP) | VAF 81/456 reads (18%) | called by muse, mutect2, varscan2
- C11orf71 | c.358C>A p.L120M | Missense Mutation (SNP) | VAF 63/324 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- C12orf40 | c.645T>A p.H215Q | Missense Mutation (SNP) | VAF 117/756 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CAND1 | c.239A>G p.K80R | Missense Mutation (SNP) | VAF 82/357 reads (23%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- CANX | c.481G>T p.G161C | Missense Mutation (SNP) | VAF 102/348 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CASKIN1 | c.4118T>A p.L1373Q | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- CDC42BPA | c.243G>T p.K81N | Missense Mutation (SNP) | VAF 81/714 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CDK11B | c.1502G>T p.R501I | Missense Mutation (SNP) | VAF 68/340 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CEBPZ | c.1143G>C p.K381N | Missense Mutation (SNP) | VAF 86/358 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- CENPI | c.2178G>T p.Q726H | Missense Mutation (SNP) | VAF 238/781 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.633); called by muse, mutect2, varscan2
- CHM | c.996C>A p.N332K | Missense Mutation (SNP) | VAF 143/638 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- CHTF18 | c.925A>C p.K309Q | Missense Mutation (SNP) | VAF 52/280 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CMKLR1 | c.905C>A p.T302N (on ENST00000312143 / NM_001142344.2; = p.T300N on NM_004072.3) | Missense Mutation (SNP) | VAF 82/296 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- CNN3 | c.875G>A p.G292D | Missense Mutation (SNP) | VAF 169/830 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CNTN3 | c.859T>A p.F287I | Missense Mutation (SNP) | VAF 92/408 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.331); called by muse, varscan2
- COL4A3 | c.958C>A p.P320T | Missense Mutation (SNP) | VAF 194/817 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CRBN | c.1270C>T p.P424S | Missense Mutation (SNP) | VAF 14/433 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- CRYBA2 | c.489T>A p.Y163* | Nonsense Mutation (SNP) | VAF 64/278 reads (23%) | called by muse, mutect2, varscan2
- CTSV | c.977_978insG p.T327Hfs*11 | Frame Shift Ins (INS) | VAF 33/141 reads (23%) | called by mutect2, pindel, varscan2
- CUX2 | c.1624G>T p.G542* | Nonsense Mutation (SNP) | VAF 24/84 reads (29%) | called by muse, mutect2
- CYP1A1 | c.544G>T p.G182W | Missense Mutation (SNP) | VAF 61/207 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CYP2D6 | c.332G>A p.G111D | Missense Mutation (SNP) | VAF 80/352 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- DEGS1 | c.434C>A p.P145H | Missense Mutation (SNP) | VAF 136/503 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNMT3B | c.728T>C p.V243A | Missense Mutation (SNP) | VAF 110/425 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- DSP | c.3326A>C p.E1109A | Missense Mutation (SNP) | VAF 112/878 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- EARS2 | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 21/150 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EML6 | c.3016G>C p.A1006P | Missense Mutation (SNP) | VAF 63/279 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ETAA1 | c.1232C>T p.T411I | Missense Mutation (SNP) | VAF 78/369 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- EZR | c.833A>T p.K278M | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- FLG | c.8694G>T p.E2898D | Missense Mutation (SNP) | VAF 178/567 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- FLT3 | c.221C>G p.T74R | Missense Mutation (SNP) | VAF 75/289 reads (26%) | SIFT tolerated (0.56); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- FRMD4B | c.1567G>A p.E523K | Missense Mutation (SNP) | VAF 171/684 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- FRMPD2 | c.1130T>A p.L377H | Missense Mutation (SNP) | VAF 154/592 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FSIP2 | c.20639T>C p.M6880T | Missense Mutation (SNP) | VAF 131/562 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- GATAD2A | c.1344G>T p.K448N | Missense Mutation (SNP) | VAF 167/461 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- GGT7 | c.67A>T p.S23C | Missense Mutation (SNP) | VAF 4/81 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- GGT7 | c.66G>T p.M22I | Missense Mutation (SNP) | VAF 4/81 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.827); called by muse, mutect2
- GIGYF2 | c.2017C>G p.Q673E | Missense Mutation (SNP) | VAF 74/586 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, varscan2
- GIGYF2 | c.3856G>C p.E1286Q | Missense Mutation (SNP) | VAF 142/644 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- HAO2 | c.1052T>G p.L351R | Missense Mutation (SNP) | VAF 98/406 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- HID1 | c.116C>T p.T39I | Missense Mutation (SNP) | VAF 78/202 reads (39%) | SIFT tolerated (0.49); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- HID1 | c.115A>C p.T39P | Missense Mutation (SNP) | VAF 76/198 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HIVEP1 | c.7618C>A p.H2540N | Missense Mutation (SNP) | VAF 47/259 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- HLTF | c.2954T>G p.F985C | Missense Mutation (SNP) | VAF 24/574 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2
- HNRNPR | c.1726G>C p.D576H | Missense Mutation (SNP) | VAF 43/231 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- HRNR | c.1382_1398del p.Y461Sfs*5 | Frame Shift Del (DEL) | VAF 51/553 reads (9%) | called by mutect2, pindel
- HSPA13 | c.386T>C p.M129T | Missense Mutation (SNP) | VAF 64/384 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- IFNA2 | c.473A>G p.Y158C | Missense Mutation (SNP) | VAF 126/390 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- IGSF9B | c.1763T>C p.L588P | Missense Mutation (SNP) | VAF 35/176 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IL4R | c.2261C>T p.P754L | Missense Mutation (SNP) | VAF 47/168 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- KCNJ3 | c.343G>T p.A115S | Missense Mutation (SNP) | VAF 113/534 reads (21%) | SIFT tolerated (0.68); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- KDM5B | c.2445G>C p.Q815H | Missense Mutation (SNP) | VAF 89/320 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- KIFBP | c.386G>A p.R129Q | Missense Mutation (SNP) | VAF 71/242 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- LAMA5 | c.4797G>T p.K1599N | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); called by muse, mutect2
- MCOLN3 | c.1487T>C p.L496P | Missense Mutation (SNP) | VAF 70/572 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MICALL2 | c.944A>G p.H315R | Missense Mutation (SNP) | VAF 81/311 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- MMUT | c.65C>A p.S22* | Nonsense Mutation (SNP) | VAF 41/297 reads (14%) | called by muse, mutect2, varscan2
- MUC17 | c.8301G>T p.E2767D | Missense Mutation (SNP) | VAF 72/183 reads (39%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- MYT1L | c.861C>G p.D287E | Missense Mutation (SNP) | VAF 109/466 reads (23%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NCOA1 | c.2552C>A p.P851Q | Missense Mutation (SNP) | VAF 60/254 reads (24%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- NES | c.2708T>A p.L903* | Nonsense Mutation (SNP) | VAF 97/285 reads (34%) | called by muse, mutect2, varscan2
- NPY1R | c.613G>T p.D205Y | Missense Mutation (SNP) | VAF 119/416 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- NWD1 | c.1321G>T p.D441Y | Missense Mutation (SNP) | VAF 54/165 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- OR2M3 | c.223T>A p.C75S | Missense Mutation (SNP) | VAF 46/300 reads (15%) | SIFT tolerated (0.77); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- PIGA | c.1350C>G p.I450M | Missense Mutation (SNP) | VAF 93/408 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, varscan2
- PKDREJ | c.6235C>A p.Q2079K | Missense Mutation (SNP) | VAF 42/238 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- PKHD1 | c.5942T>C p.I1981T | Missense Mutation (SNP) | VAF 125/445 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- PLA2G2A | c.402T>A p.N134K | Missense Mutation (SNP) | VAF 129/666 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- PLA2G4E | c.230T>A p.M77K | Missense Mutation (SNP) | VAF 78/305 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.716); called by muse, mutect2, varscan2
- PLEKHH2 | c.129A>C p.Q43H | Missense Mutation (SNP) | VAF 62/234 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PPFIA2 | c.3119_3121del p.Y1040del | In Frame Del (DEL) | VAF 69/515 reads (13%) | called by mutect2, pindel, varscan2
- PPP1R26 | c.445C>T p.Q149* | Nonsense Mutation (SNP) | VAF 12/29 reads (41%) | called by muse, mutect2, varscan2
- PRDM9 | c.693C>G p.D231E | Missense Mutation (SNP) | VAF 139/600 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PREX2 | c.2114del p.X705_splice | Splice Site (DEL) | VAF 34/197 reads (17%) | called by mutect2, pindel, varscan2
- PRKN | c.756_770del p.Q252_R256del | In Frame Del (DEL) | VAF 98/850 reads (12%) | called by mutect2, pindel
- PXDN | c.578C>A p.T193K | Missense Mutation (SNP) | VAF 65/380 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- RAB29 | c.580C>G p.Q194E | Missense Mutation (SNP) | VAF 151/650 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RB1CC1 | c.4268G>T p.R1423I | Missense Mutation (SNP) | VAF 92/400 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- RBM33 | c.1685T>A p.L562Q | Missense Mutation (SNP) | VAF 51/248 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.592); called by muse, mutect2, varscan2
- RESP18 | c.486C>A p.N162K | Missense Mutation (SNP) | VAF 91/357 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- RNF32 | c.981C>A p.H327Q | Missense Mutation (SNP) | VAF 64/596 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ROBO4 | c.2602C>A p.P868T | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- SCAP | c.3309G>C p.V1103= | Splice Region (SNP) | VAF 8/241 reads (3%) | called by muse, mutect2
- SEM1 | c.101G>T p.R34I | Missense Mutation (SNP) | VAF 349/915 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SERPINA12 | c.812T>C p.I271T | Missense Mutation (SNP) | VAF 99/404 reads (25%) | SIFT tolerated (0.71); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- SFSWAP | c.1864A>G p.N622D | Missense Mutation (SNP) | VAF 112/676 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SI | c.4147A>C p.N1383H | Missense Mutation (SNP) | VAF 73/604 reads (12%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- SLC23A2 | c.1303G>T p.G435W | Missense Mutation (SNP) | VAF 98/505 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC6A15 | c.11dup p.N4Kfs*2 | Frame Shift Ins (INS) | VAF 26/212 reads (12%) | called by pindel, varscan2
- SMARCA4 | c.1450A>T p.K484* | Nonsense Mutation (SNP) | VAF 186/504 reads (37%) | called by muse, mutect2, varscan2
- SMG1 | c.7828G>A p.A2610T | Missense Mutation (SNP) | VAF 51/183 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- SOX11 | c.272A>G p.K91R | Missense Mutation (SNP) | VAF 72/334 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- SPTA1 | c.4265A>T p.D1422V | Missense Mutation (SNP) | VAF 74/657 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- STN1 | c.403A>T p.R135* | Nonsense Mutation (SNP) | VAF 128/582 reads (22%) | called by muse, mutect2, varscan2
- SUPT6H | c.1310C>G p.A437G | Missense Mutation (SNP) | VAF 95/284 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.056); called by muse, varscan2
- SYNGAP1 | c.644G>T p.G215V | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TENM4 | c.6505C>G p.Q2169E | Missense Mutation (SNP) | VAF 63/295 reads (21%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- TEX13C | c.2170G>T p.A724S | Missense Mutation (SNP) | VAF 179/622 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.003); called by muse, varscan2
- TEX50 | c.464C>A p.P155H | Missense Mutation (SNP) | VAF 97/786 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- TNXB | c.7466G>T p.G2489V (on ENST00000647633; = p.G2242V on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TOM1 | c.1224+1G>A p.X408_splice | Splice Site (SNP) | VAF 27/144 reads (19%) | called by muse, mutect2, varscan2
- TOP2B | c.1872A>C p.E624D (on ENST00000264331 / NM_001330700.2; = p.E619D on NM_001068.3) | Missense Mutation (SNP) | VAF 100/391 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TSBP1 | c.942del p.T315Qfs*19 (on ENST00000617061; = p.G318Dfs*6 on NM_006781.5) | Frame Shift Del (DEL) | VAF 42/348 reads (12%) | called by mutect2, pindel, varscan2
- TTN | c.23525C>T p.A7842V (on ENST00000591111; = p.A6915V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 68/253 reads (27%) | PolyPhen benign (0.029); called by muse, mutect2, varscan2
- TUBB8 | c.351G>T p.M117I | Missense Mutation (SNP) | VAF 115/487 reads (24%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ULK1 | c.3022C>T p.H1008Y | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- UNC13C | c.287T>C p.V96A | Missense Mutation (SNP) | VAF 90/493 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- VCAN | c.2624C>G p.A875G | Missense Mutation (SNP) | VAF 38/432 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.024); called by muse, mutect2
- VPS13C | c.8236A>C p.T2746P (on ENST00000644861 / NM_020821.3; = p.T2703P on NM_017684.5) | Missense Mutation (SNP) | VAF 77/276 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- ZFHX4 | c.4000C>A p.L1334I | Missense Mutation (SNP) | VAF 54/208 reads (26%) | SIFT tolerated (0.51); PolyPhen benign (0.001); called by muse, varscan2
- ZNF831 | c.3770C>G p.P1257R | Missense Mutation (SNP) | VAF 82/339 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ZNF846 | c.769A>G p.K257E | Missense Mutation (SNP) | VAF 96/300 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- ZXDB | c.160G>T p.G54W | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); called by muse, varscan2
- ARAP3 | c.4458C>G p.L1486= | Silent (SNP) | VAF 34/79 reads (43%) | called by muse, varscan2
- ARAP3 | c.4317C>T p.L1439= | Silent (SNP) | VAF 98/279 reads (35%) | called by muse, varscan2
- ASCL1 | c.84A>T p.A28= | Silent (SNP) | VAF 42/179 reads (23%) | called by muse, varscan2
- ATAD2B | c.72G>T p.G24= | Silent (SNP) | VAF 31/277 reads (11%) | called by muse, mutect2, varscan2
- C1orf185 | c.585G>A p.L195= | Silent (SNP) | VAF 68/158 reads (43%) | catalogued as rs1005662481; called by muse, varscan2
- CBLN2 | c.195G>C p.L65= | Silent (SNP) | VAF 45/230 reads (20%) | called by muse, mutect2, varscan2
- CCDC141 | c.3030G>T p.L1010= | Silent (SNP) | VAF 204/964 reads (21%) | called by muse, mutect2, varscan2
- CD33 | c.357G>C p.R119= | Silent (SNP) | VAF 12/34 reads (35%) | called by muse, mutect2, varscan2
- CNNM4 | c.522G>A p.E174= | Silent (SNP) | VAF 69/228 reads (30%) | called by muse, mutect2, varscan2
- CXorf38 | c.210C>T p.A70= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as rs1362396784; called by muse, mutect2, varscan2
- DACH1 | c.981T>A p.A327= | Silent (SNP) | VAF 54/142 reads (38%) | called by muse, mutect2, varscan2
- DGLUCY | c.1245A>C p.A415= | Silent (SNP) | VAF 95/442 reads (21%) | called by muse, mutect2, varscan2
- DNAH2 | c.9855G>A p.G3285= | Silent (SNP) | VAF 81/212 reads (38%) | called by muse, varscan2
- EYA2 | c.123G>C p.S41= | Silent (SNP) | VAF 71/342 reads (21%) | called by muse, mutect2, varscan2
- FABP1 | c.327C>T p.I109= | Silent (SNP) | VAF 31/140 reads (22%) | called by muse, mutect2, varscan2
- GOLGA6L2 | c.237G>A p.L79= | Silent (SNP) | VAF 64/340 reads (19%) | catalogued as COSV61485998; called by muse, mutect2, varscan2
- GPR52 | c.960C>T p.S320= | Silent (SNP) | VAF 44/398 reads (11%) | called by muse, mutect2, varscan2
- GRM6 | c.1602C>A p.V534= | Silent (SNP) | VAF 50/127 reads (39%) | catalogued as COSV51449185; called by muse, mutect2, varscan2
- HCN1 | c.1182C>G p.T394= | Silent (SNP) | VAF 147/685 reads (21%) | catalogued as COSV100302482, COSV57504508, COSV57532447; called by muse, mutect2, varscan2
- HCRT | c.61C>T p.L21= | Silent (SNP) | VAF 30/80 reads (38%) | catalogued as rs761205881; called by mutect2, varscan2
- LHFPL2 | c.12C>G p.V4= | Silent (SNP) | VAF 27/66 reads (41%) | called by muse, mutect2, varscan2
- LIN7A | c.312C>T p.S104= | Silent (SNP) | VAF 41/248 reads (17%) | catalogued as COSV54018233; called by muse, mutect2, varscan2
- LRP1B | c.8109T>A p.G2703= | Silent (SNP) | VAF 164/778 reads (21%) | called by muse, varscan2
- MMP20 | c.1392T>C p.Y464= | Silent (SNP) | VAF 169/913 reads (19%) | called by muse, mutect2, varscan2
- NUMA1 | c.3150G>A p.E1050= | Silent (SNP) | VAF 131/399 reads (33%) | called by muse, mutect2, varscan2
- OSBP | c.1440C>T p.T480= | Silent (SNP) | VAF 151/794 reads (19%) | catalogued as rs751763534; called by muse, mutect2, varscan2
- P2RX1 | c.33C>A p.A11= | Silent (SNP) | VAF 52/172 reads (30%) | called by muse, mutect2, varscan2
- PIGT | c.9G>A p.A3= | Silent (SNP) | VAF 36/185 reads (19%) | catalogued as rs750005377; called by muse, mutect2, varscan2
- RHAG | c.1056C>A p.G352= | Silent (SNP) | VAF 94/753 reads (12%) | called by muse, mutect2, varscan2
- RMDN1 | c.720C>T p.T240= | Silent (SNP) | VAF 121/569 reads (21%) | called by muse, mutect2, varscan2
- SHMT2 | c.906G>A p.K302= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as rs772801046; called by muse, mutect2, varscan2
- SLC23A2 | c.1302T>C p.T434= | Silent (SNP) | VAF 100/510 reads (20%) | catalogued as COSV57780705; called by muse, mutect2, varscan2
- SLC30A10 | c.489C>T p.V163= | Silent (SNP) | VAF 26/148 reads (18%) | catalogued as COSV63070982; called by muse, mutect2, varscan2
- SOWAHD | c.237G>T p.G79= | Silent (SNP) | VAF 12/37 reads (32%) | called by muse, mutect2, varscan2
- SPAG17 | c.336A>T p.A112= | Silent (SNP) | VAF 121/373 reads (32%) | called by muse, varscan2
- SPEG | c.3027G>A p.Q1009= | Silent (SNP) | VAF 70/192 reads (36%) | called by muse, mutect2, varscan2
- SSC5D | c.4074C>G p.V1358= | Silent (SNP) | VAF 108/268 reads (40%) | called by muse, mutect2, varscan2
- STN1 | c.402C>T p.V134= | Silent (SNP) | VAF 125/582 reads (21%) | called by muse, mutect2, varscan2
- TACR2 | c.184C>A p.R62= | Silent (SNP) | VAF 74/275 reads (27%) | called by muse, mutect2, varscan2
- THSD7A | c.4368G>A p.Q1456= | Silent (SNP) | VAF 72/359 reads (20%) | catalogued as rs1463008280; called by muse, mutect2, varscan2
- TPTE | c.339A>T p.L113= (on ENST00000618007 / NM_199261.4; = p.L95= on NM_199259.4) | Silent (SNP) | VAF 114/703 reads (16%) | called by muse, mutect2, varscan2
- AC133561.1 | n.1504G>C | RNA (SNP) | VAF 37/188 reads (20%) | called by muse, mutect2, varscan2
- ACP2 | c.639+67G>T | Intron (SNP) | VAF 118/332 reads (36%) | called by muse, mutect2, varscan2
- ADGRL2 | c.1821+24T>A | Intron (SNP) | VAF 117/303 reads (39%) | called by muse, mutect2, varscan2
- AKAP6 | c.*169_*170del | 3'UTR (DEL) | VAF 72/374 reads (19%) | called by pindel, varscan2
- AL121890.4 | chr20:5069331 G>A | 5'Flank (SNP) | VAF 47/189 reads (25%) | catalogued as rs907868028, COSV100716954; called by muse, mutect2, varscan2
- ATP13A2 | c.-44G>A | 5'UTR (SNP) | VAF 8/46 reads (17%) | catalogued as rs1429920724; called by muse, mutect2, varscan2
- ATXN2L | c.299+891C>T | Intron (SNP) | VAF 23/111 reads (21%) | called by muse, mutect2, varscan2
- CD99L2 | c.130+1910_130+1923del | Intron (DEL) | VAF 22/120 reads (18%) | called by mutect2, pindel, varscan2
- CDKN3 | c.-20T>G | 5'UTR (SNP) | VAF 9/47 reads (19%) | called by muse, mutect2, varscan2
- CENPH | c.-19C>T | 5'UTR (SNP) | VAF 55/192 reads (29%) | called by muse, mutect2, varscan2
- CST9LP1 | n.100G>C | RNA (SNP) | VAF 28/117 reads (24%) | called by muse, mutect2, varscan2
- DAO | chr12:108879706 A>C | 5'Flank (SNP) | VAF 67/272 reads (25%) | called by muse, mutect2, varscan2
- DBI | c.-31G>A | 5'UTR (SNP) | VAF 74/213 reads (35%) | called by muse, mutect2, varscan2
- ELAPOR2 | c.2169+396G>C | Intron (SNP) | VAF 324/919 reads (35%) | called by muse, mutect2, varscan2
- FOXA1 | c.72+717G>A | Intron (SNP) | VAF 122/551 reads (22%) | called by muse, mutect2, varscan2
- FRMD8P1 | n.816C>A | RNA (SNP) | VAF 24/161 reads (15%) | called by muse, mutect2, varscan2
- GRM8 | c.727+48352G>C | Intron (SNP) | VAF 196/383 reads (51%) | called by muse, mutect2, varscan2
- HPGDS | c.*2T>A | 3'UTR (SNP) | VAF 32/81 reads (40%) | called by muse, varscan2
- ISCU | c.115-219del | Intron (DEL) | VAF 120/656 reads (18%) | catalogued as COSV99934347; called by pindel, varscan2
- KANK1 | c.*10A>G | 3'UTR (SNP) | VAF 86/249 reads (35%) | called by muse, mutect2, varscan2
- KDELR2 | c.*138A>T | 3'UTR (SNP) | VAF 26/460 reads (6%) | called by muse, mutect2
- KDM4B | c.1115+605G>T | Intron (SNP) | VAF 60/160 reads (38%) | called by muse, mutect2, varscan2
- MRPS16 | c.*1587A>T | 3'UTR (SNP) | VAF 78/413 reads (19%) | called by muse, mutect2, varscan2
- NDUFB10 | chr16:1965184 G>C | 3'Flank (SNP) | VAF 35/169 reads (21%) | called by muse, mutect2, varscan2
- PPM1L | c.399+85549G>T | Intron (SNP) | VAF 89/369 reads (24%) | called by muse, mutect2, varscan2
- PRDM9 | c.-8C>A | 5'UTR (SNP) | VAF 104/500 reads (21%) | called by muse, mutect2, varscan2
- PRKRIP1 | chr7:102396173 G>T | 5'Flank (SNP) | VAF 38/165 reads (23%) | called by muse, mutect2, varscan2
- RIMS2 | c.2084-942G>C | Intron (SNP) | VAF 18/376 reads (5%) | catalogued as rs910081914; called by muse, mutect2
- RNF170 | c.-8+104C>T | Intron (SNP) | VAF 25/78 reads (32%) | called by muse, mutect2, varscan2
- RTN2 | c.-10G>A | 5'UTR (SNP) | VAF 26/71 reads (37%) | called by muse, mutect2, varscan2
- RUVBL1 | c.1211+64T>C | Intron (SNP) | VAF 29/124 reads (23%) | called by muse, mutect2, varscan2
- SHROOM4 | c.*28C>G | 3'UTR (SNP) | VAF 98/539 reads (18%) | catalogued as COSV99173369; called by muse, mutect2, varscan2
- SLC66A1L | n.443+6295G>A | Intron (SNP) | VAF 50/216 reads (23%) | called by muse, mutect2, varscan2
- SORBS1 | c.2128+1007C>T | Intron (SNP) | VAF 64/240 reads (27%) | called by muse, mutect2, varscan2
- SPHK2 | c.872+72C>T | Intron (SNP) | VAF 62/141 reads (44%) | called by muse, mutect2, varscan2
- SRI | c.511+78A>T | Intron (SNP) | VAF 47/150 reads (31%) | called by muse, mutect2, varscan2
- THSD4 | c.*3376G>A | 3'UTR (SNP) | VAF 47/167 reads (28%) | called by muse, mutect2, varscan2
